Somatic mutation profile of tumor specimen TARGET-10-PATXAL-09A (aliquot TARGET-10-PATXAL-09A-01D) from TARGET case TARGET-10-PATXAL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.4 years (5,626 days).
Specimen TARGET-10-PATXAL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05b3e698-4d6a-4eec-8049-04d9f791084b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATXAL-10A (Blood Derived Normal), aliquot TARGET-10-PATXAL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06aa739c-0d36-464f-a626-0a3cbf7c88b8

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Frame Shift Ins 3, In Frame Ins 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACBD4 | c.239G>T p.S80I | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1267825733, COSV58854121; called by muse, varscan2
- CABS1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs773366011, COSV56734988; called by muse, mutect2, varscan2
- CILP | c.1970A>G p.Y657C | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1175505861, COSV56029071; called by muse, mutect2
- CNOT3 | c.2127C>G p.H709Q | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55369297; called by muse, mutect2, varscan2
- IFT81 | c.719T>C p.L240S | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV54367675; called by muse, mutect2, varscan2
- IL13RA2 | c.318C>G p.H106Q | Missense Mutation (SNP) | VAF 47/50 reads (94%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV54568162; called by muse, mutect2, varscan2
- KDM6A | c.1252A>T p.S418C | Missense Mutation (SNP) | VAF 54/59 reads (92%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.789); catalogued as COSV65042328, COSV65048575; called by muse, mutect2, varscan2
- LRRK2 | c.4613G>A p.R1538H | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs200631999, COSV54161630; called by muse, mutect2, varscan2
- NOTCH1 | c.5153T>C p.I1718T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53036974, COSV53072017; called by muse, mutect2, varscan2
- PCDHB7 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.627); catalogued as rs558696629, COSV50794466; called by muse, mutect2, varscan2
- PIK3C2G | c.3504G>T p.E1168D (on ENST00000676171; = p.E1127D on NM_004570.5) | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56842025; called by muse, varscan2
- PLCE1 | c.4928T>C p.M1643T | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as COSV53378244; called by muse, mutect2, varscan2
- TECTA | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 66/245 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.444); catalogued as rs1365484902, COSV50778985; called by muse, mutect2, varscan2
- TTN | c.27164C>T p.S9055F (on ENST00000591111; = p.S8128F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | PolyPhen possibly damaging (0.66); catalogued as COSV59863700; called by muse, mutect2, varscan2
- UBE2I | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV57647501, COSV57649070; called by muse, mutect2, varscan2
- ZNF22 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.556); catalogued as rs752505124, COSV53584893; called by muse, mutect2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- DOC2A | c.635G>T p.C212F | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.277); called by muse, mutect2
- FBXW7 | c.2001dup p.S668Efs*26 (on ENST00000281708 / NM_001349798.2; = p.S588Efs*26 on NM_018315.5) | Frame Shift Ins (INS) | VAF 44/316 reads (14%) | called by mutect2, pindel, varscan2
- IL1RAP | c.1031C>A p.A344E | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.021); called by muse, mutect2
- ITPR2 | c.6643_6643+1insAGA p.R2214_N2215insK | In Frame Ins (INS) | VAF 7/11 reads (64%) | called by mutect2, varscan2
- KIF15 | c.607C>A p.Q203K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.115); called by muse, mutect2
- LTN1 | c.2312G>T p.W771L | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- MERTK | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); called by muse, mutect2
- MROH1 | c.1463T>C p.L488P | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- VPS37B | c.241dup p.Q81Pfs*5 | Frame Shift Ins (INS) | VAF 43/91 reads (47%) | called by mutect2, pindel, varscan2
- DDR1 | c.633C>T p.N211= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs150954035; called by muse, varscan2
- NLRP11 | c.1413C>A p.I471= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1429055971, COSV100789640; called by muse, mutect2, varscan2
- OPRM1 | c.1131C>A p.S377= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100000942; called by muse, mutect2
- PCNX3 | c.760C>T p.L254= | Silent (SNP) | VAF 16/23 reads (70%) | called by muse, mutect2, varscan2
- PRELP | c.303G>T p.P101= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as COSV58114932; called by muse, mutect2, varscan2
- COPZ1 | c.19-3299T>C | Intron (SNP) | VAF 115/230 reads (50%) | called by muse, mutect2, varscan2
- PTCHD1 | c.*14G>T | 3'UTR (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
